Somatic mutation profile of tumor specimen TCGA-FW-A3TU-06A (aliquot TCGA-FW-A3TU-06A-11D-A23B-08) from TCGA case TCGA-FW-A3TU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.7 years (28,031 days).
Specimen TCGA-FW-A3TU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb5c4d12-43fc-4cbf-a095-93e6afd0ab5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FW-A3TU-10A (Blood Derived Normal), aliquot TCGA-FW-A3TU-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d13d91bd-5af2-4e42-82f7-ed5078e07c3d

The open-access MAF lists 943 somatic variants for this specimen: 607 protein-altering or splice-affecting, 308 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 548, Silent 308, Nonsense Mutation 41, Intron 12, Splice Region 9, RNA 9, Splice Site 6, Frame Shift Del 3, 5'UTR 2, 5'Flank 2, 3'Flank 2, 3'UTR 1.

Variants (750 of 943; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNJ2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894578, CM013395, COSV54662579; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- MYH7 | c.5534G>A p.R1845Q | Missense Mutation (SNP) | VAF 121/276 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs730880822, COSV62521001; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.2850G>A p.Q950= | Splice Region (SNP) | VAF 31/105 reads (30%) | catalogued as rs863224446, CS1512929, COSV100648578, COSV62209219; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs531579697, COSV59389051; called by muse, mutect2
- ABCA1 | c.3667C>T p.H1223Y | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV66065015; called by muse, mutect2, varscan2
- ABCC8 | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM121251, COSV56853216; called by muse, mutect2, varscan2
- ABCC9 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV53977157; called by muse, mutect2, varscan2
- ABHD16B | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs763173099, COSV53863194; called by muse, mutect2
- ABHD17C | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51918167; called by muse, mutect2, varscan2
- ABTB2 | c.2609T>A p.F870Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV54391381; called by muse, mutect2, varscan2
- ACAD10 | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as rs752637658, COSV100564262; called by muse, mutect2, varscan2
- ACAD10 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564263; called by muse, mutect2, varscan2
- ACSBG2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV53123187; called by muse, mutect2, varscan2
- ADAM32 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs957652162, COSV65950171; called by muse, mutect2, varscan2
- ADAMTS17 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs142108260; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 123/226 reads (54%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADAMTS7 | c.4915G>A p.D1639N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1166787774, COSV66308136; called by muse, mutect2, varscan2
- ADGRG7 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV56298437; called by muse, mutect2, varscan2
- ADGRL2 | c.2573C>T p.S858F (on ENST00000370717 / NM_001366005.1; = p.S845F on NM_012302.4) | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV54650682; called by muse, mutect2, varscan2
- ADGRL2 | c.4186C>T p.P1396S (on ENST00000370717 / NM_001366005.1; = p.P1340S on NM_012302.4) | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV54675255; called by muse, mutect2, varscan2
- ADGRV1 | c.12371C>T p.S4124L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67989202; called by muse, mutect2, varscan2
- AFF4 | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54796507; called by muse, varscan2
- AGTPBP1 | c.2651G>C p.G884A (on ENST00000357081 / NM_001330701.2; = p.G844A on NM_015239.2) | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61274003; called by muse, mutect2, varscan2
- AIM2 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63700539; called by muse, mutect2, varscan2
- AIMP1 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1291231239, COSV100786180; called by muse, mutect2
- AIMP1 | c.391+1G>A p.X131_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as rs1187727327; called by muse, mutect2
- AKAP17A | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1402167108, COSV58310757; called by muse, mutect2, varscan2
- AKAP4 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs1557204021, COSV62074851; called by muse, mutect2, varscan2
- AKAP9 | c.5103A>T p.K1701N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV62350937; called by muse, mutect2, varscan2
- ALG1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV52158327; called by muse, mutect2, varscan2
- ALMS1 | c.6121C>T p.Q2041* | Nonsense Mutation (SNP) | VAF 87/203 reads (43%) | catalogued as COSV52513897; called by muse, mutect2, varscan2
- ANAPC1 | c.4981C>T p.H1661Y | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV61977343; called by muse, mutect2, varscan2
- ANO4 | c.2057C>T p.P686L (on ENST00000392977 / NM_001286615.2; = p.P651L on NM_178826.4) | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54583739, COSV54602500; called by muse, mutect2, varscan2
- AOAH | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs142388741; called by muse, mutect2, varscan2
- AP002512.3 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as COSV54407599; called by muse, mutect2, varscan2
- AP1B1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369916638; called by muse, mutect2, varscan2
- APLP2 | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841982; called by muse, mutect2, varscan2
- APOB | c.4699G>A p.E1567K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as rs570097888, COSV51942076; called by muse, mutect2, varscan2
- APOBEC3D | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53327227; called by muse, mutect2, varscan2
- AR | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV65959233; called by muse, mutect2, varscan2
- ARHGAP29 | c.1976A>G p.H659R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326027907, COSV53113709; called by muse, mutect2, varscan2
- ARHGAP39 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs749435106, COSV52772463; called by muse, mutect2, varscan2
- ARHGEF1 | c.327T>G p.V109= | Splice Region (SNP) | VAF 89/248 reads (36%) | catalogued as COSV61528486; called by muse, mutect2, varscan2
- ARHGEF17 | c.5662C>T p.P1888S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55238155; called by muse, mutect2, varscan2
- ARHGEF17 | c.5663C>T p.P1888L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99735816; called by muse, mutect2, varscan2
- ARHGEF25 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as rs577533598, COSV54087958; called by muse, mutect2, varscan2
- ARID5A | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100673601; called by muse, mutect2, varscan2
- ARMC4 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV59467087; called by muse, mutect2, varscan2
- ASAP1 | c.1297A>T p.S433C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63051071; called by muse, mutect2, varscan2
- ASAP2 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV99856322; called by muse, mutect2, varscan2
- ASAP2 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773110660, COSV55626846; called by muse, mutect2, varscan2
- ASTN2 | c.1616A>T p.Y539F (on ENST00000313400 / NM_001365069.1; = p.Y488F on NM_014010.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57792752; called by muse, mutect2, varscan2
- ASXL3 | c.6710C>T p.P2237L | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52471143; called by muse, mutect2, varscan2
- ATP12A | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 128/201 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV99517782; called by muse, mutect2, varscan2
- ATP13A4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs770130814, COSV55071526; called by muse, mutect2, varscan2
- B3GNT3 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57953458; called by muse, mutect2, varscan2
- BAZ2A | c.1661T>A p.L554H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99466500; called by muse, mutect2, varscan2
- BAZ2A | c.1660C>A p.L554I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.149); catalogued as COSV99466506; called by muse, mutect2, varscan2
- BICDL2 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs1204963866, COSV54156929; called by muse, mutect2, varscan2
- BICRA | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs756323742, COSV101194273; called by muse, mutect2, varscan2
- BICRA | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs969836080, COSV101194357; called by muse, mutect2, varscan2
- BLZF1 | c.850T>G p.S284A | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61394186; called by muse, mutect2, varscan2
- BNC1 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 72/80 reads (90%) | catalogued as COSV61758112; called by muse, varscan2
- BNC1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 145/164 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.198); catalogued as COSV61757551; called by muse, varscan2
- BOC | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as COSV56353919; called by muse, mutect2, varscan2
- BSN | c.7055C>T p.P2352L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV56521854; called by muse, mutect2, varscan2
- BTNL2 | c.711G>A p.E237= | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as COSV66631140; called by muse, mutect2, varscan2
- BTNL3 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100732213, COSV61565196; called by muse, mutect2, varscan2
- C11orf16 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs765220863, COSV100393898, COSV58167777, COSV58167853; called by muse, mutect2, varscan2
- C11orf87 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as rs1205783414, COSV59357381; called by muse, mutect2, varscan2
- C14orf93 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54441515; called by muse, mutect2, varscan2
- C1QTNF3 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.429); catalogued as COSV51469232; called by muse, mutect2, varscan2
- C22orf42 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.486); catalogued as COSV66076286; called by muse, mutect2, varscan2
- C2CD3 | c.5683C>T p.Q1895* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV58095121; called by muse, mutect2
- C2orf78 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV101280985, COSV68518182; called by muse, mutect2, varscan2
- C2orf78 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs756767934, COSV101280987, COSV68518293; called by muse, mutect2, varscan2
- C3 | c.3020C>T p.P1007L | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55578002; called by muse, mutect2, varscan2
- C3 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55574573, COSV99836779; called by muse, mutect2, varscan2
- C8orf34 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61385699; called by muse, mutect2, varscan2
- CABP5 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV53153194; called by muse, mutect2, varscan2
- CABP7 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.11); catalogued as rs919415422, COSV53363440; called by muse, mutect2, varscan2
- CACNA1S | c.1796A>G p.N599S | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs770075379, COSV62941304; called by muse, mutect2, varscan2
- CACNA1S | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV62941308; called by muse, mutect2, varscan2
- CAP2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV57734053; called by muse, mutect2, varscan2
- CAPN13 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs201525970, COSV54432486; called by muse, mutect2, varscan2
- CARMIL2 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100576413, COSV58028697; called by muse, mutect2, varscan2
- CATIP | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56823430; called by muse, mutect2, varscan2
- CATSPERB | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs1338631427, COSV56429364; called by muse, mutect2, varscan2
- CBLN2 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs868142587, COSV54050532; called by muse, mutect2, varscan2
- CC2D1A | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs755662350, COSV100528529, COSV100528735; called by muse, mutect2, varscan2
- CCDC191 | c.818+2T>C p.X273_splice | Splice Site (SNP) | VAF 57/189 reads (30%) | catalogued as COSV55673788; called by muse, mutect2, varscan2
- CCDC77 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53473871; called by muse, mutect2, varscan2
- CD109 | c.3925G>A p.G1309S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV54652394; called by muse, mutect2, varscan2
- CD163 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV63134606; called by muse, mutect2, varscan2
- CD1A | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 108/257 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV56862745; called by muse, mutect2, varscan2
- CD1E | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63771744; called by muse, mutect2, varscan2
- CD22 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200478498; called by muse, mutect2, varscan2
- CD6 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV57840319; called by muse, mutect2, varscan2
- CDC42BPG | c.4550C>T p.S1517F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV61348152; called by muse, mutect2, varscan2
- CDH11 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 100/146 reads (68%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.572); catalogued as COSV51767912, COSV99218814; called by muse, mutect2, varscan2
- CDH20 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53009490, COSV53012800; called by muse, mutect2, varscan2
- CDH8 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54879094; called by muse, mutect2, varscan2
- CELSR1 | c.6251G>A p.G2084E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53093802; called by mutect2, varscan2
- CEP68 | c.1687G>T p.V563F | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV53125834, COSV53126176; called by muse, mutect2, varscan2
- CFAP47 | c.2595G>A p.M865I | Missense Mutation (SNP) | VAF 91/135 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52880585; called by muse, mutect2, varscan2
- CFAP58 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs201674161, COSV57211922, COSV57212771; called by muse, mutect2, varscan2
- CHD4 | c.4070C>T p.S1357L (on ENST00000357008 / NM_001363606.2; = p.S1370L on NM_001273.5) | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58904817; called by muse, mutect2, varscan2
- CHIA | c.328G>A p.V110I (on ENST00000343320; = p.V2I on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58476519; called by muse, mutect2, varscan2
- CHST12 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324521; called by muse, mutect2, varscan2
- CHST12 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99324523; called by muse, mutect2, varscan2
- CNOT2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV57504337; called by muse, mutect2, varscan2
- CNTN2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.221); catalogued as rs868191357, COSV59351173; called by muse, mutect2, varscan2
- CNTN5 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.423); catalogued as COSV54327323; called by muse, mutect2, varscan2
- CNTNAP2 | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 92/224 reads (41%) | catalogued as COSV62211019; called by muse, mutect2, varscan2
- CNTNAP2 | c.3943G>A p.D1315N | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV62182218; called by muse, mutect2, varscan2
- CNTNAP5 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70494492; called by muse, varscan2
- COL11A2 | c.3785C>T p.P1262L (on ENST00000341947 / NM_080680.3; = p.P1155L on NM_080679.2) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59498930; called by muse, mutect2, varscan2
- COL18A1 | c.2875G>A p.G959R (on ENST00000359759 / NM_130444.3; = p.G724R on NM_030582.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700747; called by muse, mutect2, varscan2
- COL28A1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374577981; called by muse, mutect2, varscan2
- COL2A1 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV61532039; called by muse, mutect2, varscan2
- COL3A1 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs769458760, COSV58591895; called by muse, mutect2, varscan2
- COL4A4 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs778889239, COSV61631641; called by muse, mutect2, varscan2
- COL4A6 | c.3470G>A p.G1157E | Missense Mutation (SNP) | VAF 186/284 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57870907; called by muse, mutect2, varscan2
- COL5A1 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs1254955559, COSV65671284; called by muse, mutect2, varscan2
- COL5A2 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411285; called by muse, mutect2, varscan2
- COL6A1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200835287, COSV62615768; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100720259; called by muse, mutect2, varscan2
- COQ8B | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs893635174, COSV54687765; called by mutect2, varscan2
- CPA4 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99745080; called by muse, mutect2
- CPAMD8 | c.1750G>A p.E584K (on ENST00000651564; = p.E537K on NM_015692.5) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV52236474; called by muse, mutect2, varscan2
- CRISP2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs768423454, COSV59255498, COSV59256070; called by muse, mutect2, varscan2
- CRX | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV55759154; called by muse, mutect2, varscan2
- CSF1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV60034160; called by muse, mutect2, varscan2
- CSMD2 | c.3827G>A p.R1276K | Missense Mutation (SNP) | VAF 75/113 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53928986; called by muse, mutect2, varscan2
- CSMD2 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs753496611, COSV53880220; called by muse, mutect2, varscan2
- CSMD3 | c.9127G>A p.G3043R (on ENST00000297405 / NM_001363185.1; = p.G2874R on NM_052900.3) | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs138442191; called by muse, mutect2, varscan2
- CSPG4 | c.3196G>A p.G1066S | Missense Mutation (SNP) | VAF 89/115 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745355854, COSV57897686; called by muse, mutect2, varscan2
- CXorf65 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV52149199; called by muse, mutect2, varscan2
- CYB561A3 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV53652676; called by muse, mutect2, varscan2
- CYB5R4 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63751291; called by muse, mutect2, varscan2
- CYP4V2 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66505295; called by muse, mutect2, varscan2
- CYP4Z1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.168); catalogued as COSV61965652; called by muse, mutect2, varscan2
- CYYR1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs948658869, COSV54832193; called by muse, mutect2
- DCLK3 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV69363838; called by muse, varscan2
- DCLRE1B | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs773409065, COSV100849799; called by muse, mutect2, varscan2
- DCLRE1B | c.1592C>A p.P531H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100849800; called by muse, mutect2, varscan2
- DDI1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56373132; called by muse, mutect2, varscan2
- DDX27 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV65608923; called by muse, mutect2, varscan2
- DEFB105A | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100068731; called by mutect2, varscan2
- DHX34 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV60896136; called by muse, mutect2, varscan2
- DHX34 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60896142; called by muse, mutect2, varscan2
- DISC1 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.069); catalogued as rs772891200, COSV54411514; called by muse, mutect2, varscan2
- DLEC1 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV57302107; called by muse, mutect2, varscan2
- DMXL1 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 113/232 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs772847263, COSV60715571; called by muse, mutect2, varscan2
- DNAH10 | c.2097G>A p.M699I (on ENST00000409039; = p.M638I on NM_207437.3) | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV68996458; called by muse, mutect2, varscan2
- DNAH3 | c.11218G>A p.D3740N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776744687, COSV54532504; called by muse, mutect2, varscan2
- DNAH5 | c.10795C>T p.R3599C | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs202232031, COSV54209836; called by muse, mutect2, varscan2
- DNAH5 | c.10327G>A p.D3443N | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV54213154; called by muse, mutect2, varscan2
- DNMT1 | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61580856; called by muse, mutect2, varscan2
- DNMT1 | c.996-3del | Splice Region (DEL) | VAF 42/136 reads (31%) | catalogued as rs780538171; called by mutect2, pindel, varscan2
- DPYS | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59827096; called by muse, mutect2, varscan2
- DSC3 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs267605140, COSV64572327; called by muse, mutect2, varscan2
- DSG4 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs762044315, COSV57393715; called by muse, mutect2, varscan2
- DUOX1 | c.4009C>T p.R1337W | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757743378, COSV58483450; called by muse, mutect2, varscan2
- DYNC2H1 | c.11209C>T p.L3737F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs772790955, COSV62098717; called by muse, mutect2, varscan2
- EIF3K | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as COSV50264306; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57516800; called by muse, mutect2, varscan2
- ELF5 | c.595G>A p.E199K (on ENST00000312319 / NM_198381.2; = p.E189K on NM_001422.4) | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.233); catalogued as rs886064267, COSV56629199; called by muse, mutect2, varscan2
- ELOA | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs571041050, COSV69310677; called by muse, mutect2, varscan2
- ELSPBP1 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60414198; called by muse, mutect2, varscan2
- EPHA3 | c.2701C>T p.L901F | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV60713754; called by muse, mutect2, varscan2
- EPHA6 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs375352444; called by muse, mutect2, varscan2
- EPHA6 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.794); catalogued as COSV67572532, COSV67587167; called by muse, mutect2, varscan2
- EPHA7 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 64/196 reads (33%) | catalogued as COSV65169775; called by muse, mutect2, varscan2
- ERICH3 | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV58611145; called by muse, mutect2, varscan2
- ERICH3 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58611155; called by muse, mutect2, varscan2
- ESR2 | c.1010A>T p.E337V | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50833928; called by muse, mutect2, varscan2
- ESRRB | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55063523; called by muse, mutect2, varscan2
- ETS1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60094641; called by muse, mutect2, varscan2
- EVI5 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | catalogued as COSV63278732; called by muse, mutect2, varscan2
- F5 | c.2649G>A p.M883I | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1279610368, COSV63125681; called by muse, mutect2, varscan2
- FAM222A | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.885); catalogued as COSV62723656; called by muse, mutect2, varscan2
- FASTKD1 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.336); catalogued as COSV52930805, COSV52931254; called by muse, mutect2, varscan2
- FAT3 | c.12019G>A p.E4007K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV53136268; called by muse, mutect2, varscan2
- FBLN2 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368537243, COSV55487310; called by muse, mutect2
- FBN2 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52525491, COSV99324736; called by muse, mutect2, varscan2
- FBN3 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV54465154; called by muse, mutect2, varscan2
- FBXO3 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV99682214; called by muse, mutect2
- FBXO38 | c.3495T>G p.F1165L (on ENST00000340253 / NM_205836.3; = p.F1090L on NM_030793.5) | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57029162; called by muse, mutect2, varscan2
- FCRL5 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV62516648; called by muse, mutect2, varscan2
- FCRLA | c.1012C>T p.P338S (on ENST00000367959; = p.P315S on NM_032738.4) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52686733; called by muse, mutect2, varscan2
- FGF11 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53440373; called by muse, mutect2, varscan2
- FGF3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV61926000; called by mutect2, varscan2
- FHDC1 | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV99471358; called by muse, mutect2, varscan2
- FKBP6 | c.469-1G>A p.X157_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | catalogued as COSV52721265; called by muse, mutect2, varscan2
- FLG2 | c.4907G>A p.G1636E | Missense Mutation (SNP) | VAF 182/438 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs1414814823, COSV66170188; called by muse, mutect2, varscan2
- FLNA | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1475845645, COSV61046663; called by muse, mutect2, varscan2
- FMN2 | c.4094C>T p.S1365L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60438252; called by muse, mutect2, varscan2
- FRY | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV66573378; called by muse, mutect2
- FSTL4 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV54776503; called by muse, mutect2, varscan2
- FUCA1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65699343; called by muse, mutect2, varscan2
- GAB4 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV68754360; called by muse, mutect2, varscan2
- GABRA4 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV51930767, COSV99974003; called by muse, mutect2, varscan2
- GABRG1 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as COSV54957180, COSV99777259; called by muse, mutect2, varscan2
- GAD2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV52156147, COSV99393957; called by muse, mutect2, varscan2
- GAL3ST2 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99510969; called by muse, mutect2, varscan2
- GALNT10 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51729132; called by muse, mutect2, varscan2
- GBP5 | c.164T>G p.M55R | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100600136, COSV58593333; called by muse, mutect2, varscan2
- GCC1 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58462960; called by muse, mutect2, varscan2
- GCLC | c.521C>T p.S174F (on ENST00000643939; = p.S172F on NM_001498.4) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57596365; called by muse, mutect2, varscan2
- GDF10 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as rs1565748247; called by muse, mutect2, varscan2
- GDF5 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.08); catalogued as rs775031524, COSV65502129; called by muse, mutect2, varscan2
- GET3 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV62002658; called by muse, mutect2, varscan2
- GLI2 | c.3187G>A p.E1063K (on ENST00000361492 / NM_001374353.1; = p.E1080K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs1442433669, COSV58039718, COSV58045593; called by muse, mutect2, varscan2
- GLI2 | c.4618C>T p.P1540S (on ENST00000361492 / NM_001374353.1; = p.P1557S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as COSV100083405; called by muse, mutect2, varscan2
- GLIS3 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs761870225, COSV60931830; called by muse, mutect2, varscan2
- GMPS | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55810431; called by muse, mutect2, varscan2
- GPATCH1 | c.2016C>G p.H672Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99404087; called by muse, mutect2, varscan2
- GPATCH1 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs747439891, COSV99404089; called by muse, mutect2, varscan2
- GPC5 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65609684; called by muse, mutect2, varscan2
- GPR108 | c.1270C>T p.L424F (on ENST00000264080 / NM_001080452.1; = p.L182F on NM_020171.2) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51185536; called by muse, mutect2, varscan2
- GPR141 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as COSV57732962; called by muse, mutect2, varscan2
- GPR179 | c.6354G>A p.W2118* (on ENST00000621958; = p.W2117* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 56/156 reads (36%) | catalogued as rs766582295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIK1 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as rs1346295351, COSV58723767; called by muse, mutect2, varscan2
- GRIN2A | c.4371G>T p.M1457I | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV58042305; called by muse, mutect2, varscan2
- GRM2 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99622897; called by muse, mutect2, varscan2
- GRM2 | c.1461G>C p.W487C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99622900; called by muse, mutect2, varscan2
- GRM4 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV65215343; called by muse, mutect2, varscan2
- GRM6 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51445385; called by muse, mutect2, varscan2
- GYS2 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as rs750040511, COSV53925281; called by muse, mutect2, varscan2
- H2AC1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as COSV51237691; called by muse, mutect2, varscan2
- HCRTR2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs865812739, COSV63793796; called by muse, mutect2
- HEATR1 | c.6157T>G p.S2053A | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV59382073; called by muse, mutect2, varscan2
- HECTD4 | c.9224C>T p.P3075L | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (1); catalogued as COSV66394804; called by muse, mutect2, varscan2
- HELZ | c.4615C>T p.H1539Y | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs185339107, COSV100698793; called by muse, mutect2, varscan2
- HERC5 | c.2160T>A p.Y720* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | catalogued as COSV52041640; called by muse, mutect2, varscan2
- HGS | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs754070827, COSV100230547; called by muse, mutect2, varscan2
- HJV | c.1192C>T p.P398S (on ENST00000336751 / NM_213653.4; = p.P285S on NM_145277.5) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV60952464; called by muse, mutect2, varscan2
- HMCN1 | c.3119C>T p.S1040L | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as COSV54873028; called by muse, mutect2, varscan2
- HMGCS2 | c.550T>G p.S184A | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as COSV65568418; called by muse, mutect2, varscan2
- HNF4A | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV57385296; called by muse, mutect2, varscan2
- HPR | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57183640; called by muse, mutect2, varscan2
- HR | c.2900G>A p.G967E | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100455857; called by muse, mutect2, varscan2
- HR | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100455858; called by muse, mutect2, varscan2
- HS3ST3B1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100714552; called by muse, mutect2, varscan2
- HUWE1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV53340089, COSV53353106; called by muse, mutect2, varscan2
- IGHV5-51 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs1555541312; called by muse, mutect2, varscan2
- IGSF9 | c.3049C>T p.P1017S (on ENST00000368094 / NM_001135050.2; = p.P1001S on NM_020789.4) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV57422660; called by muse, mutect2, varscan2
- IHO1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV56508576; called by muse, mutect2, varscan2
- IL1A | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV54519809; called by muse, mutect2, varscan2
- INSC | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1484398263, COSV65411547; called by muse, mutect2, varscan2
- INSR | c.3965A>G p.E1322G | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV57158005; called by muse, mutect2, varscan2
- IPO7 | c.1550C>A p.A517D | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63352779; called by muse, mutect2, varscan2
- ITGA1 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | catalogued as rs1037578337, COSV50886565; called by muse, mutect2, varscan2
- ITGA4 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV51998887; called by muse, mutect2, varscan2
- ITGA5 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 58/160 reads (36%) | catalogued as COSV53215536, COSV53219093; called by muse, mutect2, varscan2
- ITGA6 | c.2419G>A p.D807N (on ENST00000442250; = p.D768N on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV51231845; called by muse, mutect2, varscan2
- ITGA9 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs749882984, COSV53240748; called by muse, mutect2, varscan2
- KALRN | c.5017G>A p.V1673I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs774954951, COSV62571498; called by muse, mutect2, varscan2
- KANSL3 | c.2209C>T p.P737S (on ENST00000666923 / NM_001349262.2; = p.P711S on NM_001115016.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV62619009; called by muse, mutect2, varscan2
- KCNA5 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs772279138, COSV99363935; called by muse, mutect2, varscan2
- KCNN3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55220461; called by muse, mutect2, varscan2
- KCNS2 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs749432677, COSV54639379; called by muse, mutect2, varscan2
- KCNT2 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54089998; called by muse, mutect2, varscan2
- KCTD7 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51877029; called by muse, mutect2, varscan2
- KDM6B | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs145085233; called by muse, mutect2, varscan2
- KHNYN | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs752693062, COSV52161886; called by muse, mutect2, varscan2
- KIAA0895L | c.1198A>T p.I400F | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51783572; called by muse, mutect2, varscan2
- KIAA1217 | c.5785G>A p.G1929R | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56817036; called by muse, mutect2, varscan2
- KIF13A | c.2755G>C p.D919H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV52456781; called by muse, mutect2, varscan2
- KIFBP | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62555580; called by muse, mutect2, varscan2
- KLHL10 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV53173896, COSV53174275; called by muse, mutect2, varscan2
- KLHL14 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1024322222, COSV63833829; called by muse, mutect2, varscan2
- KLHL40 | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV55135526; called by muse, mutect2, varscan2
- KMT2A | c.10480G>A p.G3494R | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV100629030; called by muse, mutect2, varscan2
- KMT2A | c.10481G>A p.G3494E | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1302416736, COSV100629031; called by muse, mutect2, varscan2
- KRT26 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138784431; called by muse, mutect2, varscan2
- KRT74 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as rs1265609594, COSV59772374, COSV59772578; called by muse, mutect2, varscan2
- KRT75 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV52873652; called by muse, mutect2, varscan2
- KRT75 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV52873662; called by muse, mutect2
- KRT75 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52873676; called by muse, mutect2
- KRT9 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.073); catalogued as COSV55854087; called by muse, mutect2, varscan2
- LAMA5 | c.8315A>T p.E2772V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53363976; called by muse, mutect2, varscan2
- LBP | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as COSV54143649; called by muse, mutect2, varscan2
- LHFPL2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV66715217; called by muse, mutect2
- LINGO4 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100561962; called by muse, mutect2, varscan2
- LIPI | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867097666, COSV60709067; called by muse, mutect2, varscan2
- LRFN2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs376487545; called by muse, mutect2, varscan2
- LRIT3 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV59986135; called by muse, mutect2, varscan2
- LRP1 | c.6740C>T p.T2247I | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs140707279, COSV54516970; called by muse, mutect2, varscan2
- LRP10 | c.1919C>G p.P640R | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV62078535; called by muse, mutect2, varscan2
- LRP3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as rs1368364179, COSV53505232; called by muse, mutect2, varscan2
- LRRC37A2 | c.4860-1G>A p.X1620_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100238766; called by mutect2, varscan2
- LRRC37A2 | c.4860G>A p.R1620= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100238767; called by mutect2, varscan2
- MAGEC1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 218/315 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs897888285, COSV53569683, COSV53574160, COSV99595844; called by muse, mutect2, varscan2
- MAGI3 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV56836584; called by muse, mutect2, varscan2
- MAMLD1 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99476108; called by muse, mutect2, varscan2
- MAN2A2 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs566619468, COSV64638313; called by muse, mutect2, varscan2
- MAP1B | c.5888C>T p.T1963I | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV99702491; called by muse, mutect2, varscan2
- MAP3K9 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776036323, COSV67121973; called by muse, mutect2, varscan2
- MAPK8IP1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53797785; called by muse, mutect2, varscan2
- MARCHF6 | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 151/246 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs775879229, COSV56878916; called by muse, mutect2, varscan2
- MBD5 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); catalogued as COSV68695936; called by muse, mutect2, varscan2
- MCTP2 | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as COSV63294911; called by muse, mutect2, varscan2
- MDP1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 132/277 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV51661004; called by muse, mutect2, varscan2
- MED6 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 55/126 reads (44%) | catalogued as COSV56449748, COSV56450565; called by muse, mutect2, varscan2
- MEMO1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs775618103, COSV54451903; called by muse, mutect2
- MERTK | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147779020, COSV54925189, COSV54925205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL17 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV53870169; called by muse, mutect2, varscan2
- MGAM | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs375177765; called by muse, mutect2, varscan2
- MGAT5B | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs376280840; called by muse, mutect2, varscan2
- MIEF1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs756813736, COSV57479629; called by muse, mutect2, varscan2
- MLH3 | c.2287A>G p.K763E | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53156613; called by muse, mutect2, varscan2
- MOGAT1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV71479957; called by muse, mutect2
- MROH1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772259019, COSV58188133, COSV58188216; called by muse, mutect2, varscan2
- MROH2B | c.3142G>A p.E1048K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV68185164, COSV68186142; called by muse, mutect2, varscan2
- MUC16 | c.10919C>T p.T3640I | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV67477211; called by muse, mutect2, varscan2
- MUC4 | c.15994G>A p.G5332R (on ENST00000463781 / NM_018406.7; = p.G1096R on NM_004532.6) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as COSV57773500; called by muse, mutect2, varscan2
- MUC4 | c.13378C>T p.P4460S (on ENST00000463781 / NM_018406.7; = p.P224S on NM_004532.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57789476; called by muse, mutect2
- MYBBP1A | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99626279; called by muse, mutect2, varscan2
- MYG1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV52933465; called by muse, mutect2, varscan2
- MYH1 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1567718869, COSV56851797; called by muse, mutect2, varscan2
- MYH4 | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55121247; called by muse, varscan2
- MYH9 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53389040; called by muse, mutect2, varscan2
- MYLK | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190877071, COSV100658880, COSV60608412; called by muse, mutect2, varscan2
- MYLK3 | c.99C>A p.N33K | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV67365103; called by muse, mutect2, varscan2
- MYO18A | c.2319G>A p.R773= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as COSV62869457; called by muse, mutect2, varscan2
- MYO7B | c.1451G>A p.W484* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV67349082; called by muse, mutect2, varscan2
- MYOM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs148337899; called by muse, mutect2, varscan2
- N4BP2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.232); catalogued as COSV54704076; called by muse, mutect2, varscan2
- NCOR2 | c.5381C>T p.S1794F | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62299273; called by muse, mutect2, varscan2
- NDRG2 | c.293T>C p.V98A (on ENST00000298687 / NM_001354570.1; = p.V84A on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV53873052; called by muse, mutect2, varscan2
- NDUFB7 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV99295113; called by muse, mutect2, varscan2
- NEBL | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.874); catalogued as COSV101009139, COSV65804251; called by muse, mutect2, varscan2
- NECTIN4 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100919930; called by muse, mutect2, varscan2
- NET1 | c.883G>A p.E295K (on ENST00000355029 / NM_001047160.3; = p.E241K on NM_005863.5) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs764163990, COSV61791883; called by muse, mutect2, varscan2
- NIBAN2 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55940876; called by muse, mutect2, varscan2
- NIN | c.2411A>T p.E804V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55396658; called by muse, mutect2, varscan2
- NLRP4 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV56714273; called by muse, mutect2, varscan2
- NLRP9 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.823); catalogued as COSV60465144; called by muse, mutect2, varscan2
- NOL4L | c.573C>T p.N191= | Splice Region (SNP) | VAF 15/54 reads (28%) | catalogued as rs202195209, COSV62889736; called by muse, mutect2, varscan2
- NOTCH1 | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1322907050, COSV53029809; called by muse, mutect2, varscan2
- NPAS4 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs1418431856, COSV60651340; called by muse, mutect2, varscan2
- NPR2 | c.2177T>C p.L726S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV61041697; called by muse, mutect2, varscan2
- NPSR1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs35436513; called by muse, mutect2, varscan2
- NPY2R | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.78); PolyPhen benign (0.078); catalogued as rs151197683, COSV61527895, COSV61528249; called by muse, mutect2
- NR5A1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as rs1380687702, COSV65295092; called by muse, mutect2, varscan2
- NRK | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV54600507; called by muse, mutect2, varscan2
- NRK | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 114/150 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1264947514, COSV54600516; called by muse, mutect2, varscan2
- NTRK3 | c.2455G>A p.E819K (on ENST00000360948 / NM_001012338.2; = p.E805K on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV62309317; called by muse, mutect2, varscan2
- NUP188 | c.5161A>G p.K1721E | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV65331346; called by muse, mutect2, varscan2
- NXPH2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV55639989; called by muse, mutect2, varscan2
- OGFRL1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100965778; called by muse, mutect2, varscan2
- OGFRL1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV100965779, COSV64972456; called by muse, mutect2, varscan2
- OLFML1 | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100252703, COSV61403141; called by muse, mutect2
- OPCML | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs1241085024, COSV59433443; called by muse, mutect2, varscan2
- OR1J2 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs759405491, COSV58944649; called by muse, mutect2, varscan2
- OR1L3 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as rs375408609; called by muse, mutect2, varscan2
- OR2B3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV65851046; called by muse, mutect2, varscan2
- OR2C3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs200581250, COSV63574834; called by muse, mutect2, varscan2
- OR2T2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs745622472, COSV100737686; called by muse, mutect2, varscan2
- OR4A16 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 81/169 reads (48%) | catalogued as rs200380532, COSV59043958; called by muse, mutect2, varscan2
- OR4C16 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1565052193, COSV58942866; called by muse, mutect2, varscan2
- OR4L1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs752850880, COSV59849502; called by muse, mutect2, varscan2
- OR52B2 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV73209461; called by muse, mutect2, varscan2
- OR52B4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV68769197; called by muse, mutect2, varscan2
- OR5M10 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV73242366; called by muse, mutect2, varscan2
- OR5M11 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); catalogued as rs775980854, COSV73141922; called by muse, mutect2, varscan2
- OR5T2 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1454466123, COSV57588197; called by muse, mutect2, varscan2
- OR6C75 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58552883; called by muse, mutect2, varscan2
- OR6X1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV60010036; called by muse, mutect2, varscan2
- OR8K3 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as rs1396981354, COSV57132100; called by muse, mutect2, varscan2
- OSBPL3 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV57658898; called by muse, mutect2, varscan2
- OTOP2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 127/379 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58882537; called by muse, mutect2, varscan2
- OTOR | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55721808, COSV55722275; called by muse, mutect2, varscan2
- P2RX3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751193989, COSV54442014; called by muse, mutect2, varscan2
- P2RY8 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs746637287, COSV67177736; called by muse, mutect2, varscan2
- PALD1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV54975527; called by muse, mutect2, varscan2
- PAN2 | c.3301C>T p.L1101F (on ENST00000425394 / NM_001127460.3; = p.L1097F on NM_014871.5) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV56264650; called by muse, mutect2, varscan2
- PCDH15 | c.4697G>A p.G1566E | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64707631; called by muse, mutect2, varscan2
- PCDH15 | c.3580G>A p.G1194R | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV57316728, COSV57342928; called by muse, mutect2, varscan2
- PCDHA2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782513202, COSV100974059, COSV65364919; called by muse, varscan2
- PCDHA2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.1); catalogued as rs148429256, COSV65366208; called by muse, varscan2
- PCDHB4 | c.358T>A p.L120I | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV52024083; called by muse, mutect2, varscan2
- PCDHGA2 | c.2197A>G p.T733A | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53979039; called by muse, mutect2, varscan2
- PCLO | c.13651G>A p.E4551K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61646695; called by muse, mutect2, varscan2
- PCLO | c.12397C>T p.R4133C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372497499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCSK5 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.362); catalogued as COSV70450755; called by muse, mutect2, varscan2
- PCYOX1 | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 179/464 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV100037014, COSV52477064; called by muse, mutect2, varscan2
- PDCD10 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV67102708; called by muse, mutect2
- PDE12 | c.1583A>G p.E528G | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV60818909; called by muse, mutect2, varscan2
- PDE1A | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59513780; called by muse, mutect2, varscan2
- PDE2A | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57809638; called by muse, mutect2, varscan2
- PDE3A | c.2456G>A p.G819E | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100762233; called by muse, mutect2, varscan2
- PDE6C | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65114990; called by muse, mutect2, varscan2
- PDGFRA | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57270281; called by muse, mutect2, varscan2
- PDZD2 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV56863509; called by muse, mutect2, varscan2
- PDZD8 | c.2018C>T p.S673L | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs906264981, COSV57825274; called by muse, mutect2, varscan2
- PDZRN4 | c.2758G>A p.E920K (on ENST00000402685 / NM_001164595.2; = p.E662K on NM_013377.4) | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54207036; called by muse, mutect2, varscan2
- PEG10 | c.340G>A p.D114N (on ENST00000482108 / NM_001040152.2; = p.D148N on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV71788415; called by muse, mutect2, varscan2
- PELP1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV52589502; called by muse, mutect2, varscan2
- PGR | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54804791; called by muse, mutect2, varscan2
- PHF2 | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV63681997; called by muse, mutect2
- PHF8 | c.1847G>C p.R616T (on ENST00000357988 / NM_001184896.1; = p.R580T on NM_015107.3) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV57683769; called by muse, mutect2, varscan2
- PIGU | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54164182; called by muse, mutect2, varscan2
- PKDREJ | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV53547215, COSV99479703; called by muse, mutect2, varscan2
- PKHD1 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV61873480; called by muse, mutect2, varscan2
- PKHD1L1 | c.10663C>T p.P3555S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV65743206, COSV65750798; called by muse, mutect2, varscan2
- PKN1 | c.759C>T p.A253= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as rs759574054, COSV99661350; called by mutect2, varscan2
- PKN1 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs1227158975, COSV99661352; called by mutect2, varscan2
- PLA2R1 | c.4310C>T p.P1437L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51781793; called by muse, mutect2, varscan2
- PLB1 | c.2494C>T p.Q832* | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as COSV59826446; called by muse, mutect2, varscan2
- PLCB1 | c.3637G>A p.D1213N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV62058192; called by muse, mutect2, varscan2
- PLCB4 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as rs747043641, COSV53793534; called by muse, mutect2, varscan2
- PLEC | c.12574C>T p.P4192S (on ENST00000322810 / NM_201380.4; = p.P4082S on NM_000445.5) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59656297; called by muse, mutect2, varscan2
- PLEC | c.7982T>G p.V2661G (on ENST00000322810 / NM_201380.4; = p.V2551G on NM_000445.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV59656333; called by muse, mutect2, varscan2
- PLRG1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57424027; called by muse, mutect2, varscan2
- PNPLA6 | c.2786C>T p.S929L (on ENST00000414982 / NM_001166111.2; = p.S881L on NM_006702.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV55380734; called by muse, mutect2, varscan2
- PODN | c.1302G>A p.M434I (on ENST00000395871; = p.M386I on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV57014979; called by muse, mutect2, varscan2
- POLE | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV57684086; called by muse, mutect2, varscan2
- POLG | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV51522977; called by muse, mutect2, varscan2
- POLR2A | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 213/487 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs779849342; called by muse, mutect2, varscan2
- POMT2 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as rs748185057, COSV55072150; called by muse, mutect2, varscan2
- PON2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV99749749; called by muse, mutect2, varscan2
- PON2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV99749752; called by muse, mutect2, varscan2
- PPARGC1B | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV58530850; called by muse, mutect2, varscan2
- PPEF1 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 76/106 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62996090; called by muse, mutect2, varscan2
- PPFIA4 | c.3428C>T p.T1143I (on ENST00000447715; = p.T1144I on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55317747; called by muse, mutect2
- PPIP5K1 | c.3250T>G p.F1084V (on ENST00000396923; = p.F1059V on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as COSV58479615; called by muse, mutect2, varscan2
- PPM1D | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as rs1285008664, COSV59956065; called by muse, mutect2, varscan2
- PPM1L | c.933A>C p.E311D | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV55566546; called by muse, mutect2, varscan2
- PPP1R14D | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100146649; called by muse, mutect2, varscan2
- PPP1R3A | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52885842, COSV52886088; called by muse, mutect2, varscan2
- PPP2R1B | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1555052727, COSV59536364; called by muse, mutect2, varscan2
- PPP4R3B | c.2454G>A p.K818= (on ENST00000616407 / NM_001122964.3; = p.K733= on NM_020463.4) | Splice Region (SNP) | VAF 85/239 reads (36%) | catalogued as rs774712335, COSV55406526; called by muse, mutect2, varscan2
- PRAM1 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55314717; called by muse, mutect2, varscan2
- PRKRIP1 | c.68T>A p.I23N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV61350244; called by muse, mutect2, varscan2
- PRLH | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV99382200; called by muse, mutect2, varscan2
- PROC | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.471); catalogued as rs1324719747, COSV52166849; called by muse, mutect2, varscan2
- PRPF8 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV59264927; called by muse, mutect2, varscan2
- PRUNE1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV54958885; called by muse, mutect2, varscan2
- PRUNE1 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.87); catalogued as COSV54847767; called by muse, mutect2, varscan2
- PRUNE2 | c.5400G>A p.W1800* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as rs763507249, COSV100944702; called by muse, mutect2, varscan2
- PRUNE2 | c.5399G>A p.W1800* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100944703; called by muse, mutect2, varscan2
- PTPRH | c.3158G>A p.R1053K | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.028); catalogued as COSV54747212, COSV99670928, COSV99671091; called by muse, mutect2, varscan2
- PWWP3B | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61800547; called by muse, mutect2, varscan2
- QRICH2 | c.2987A>T p.D996V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV53154820; called by muse, mutect2, varscan2
- RAB3A | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99718013; called by muse, mutect2, varscan2
- RASD2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53352762, COSV53352906; called by muse, mutect2, varscan2
- RASD2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV53352916; called by muse, mutect2, varscan2
- RAVER1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs952158789, COSV53346567; called by muse, mutect2, varscan2
- RB1 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 47/85 reads (55%) | catalogued as COSV57313947; called by muse, mutect2, varscan2
- RBM5 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100762343; called by muse, mutect2, varscan2
- RBM5 | c.302T>G p.M101R | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100762344; called by muse, mutect2, varscan2
- RCOR2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1257709661, COSV56850587, COSV56851606; called by muse, mutect2, varscan2
- RGL2 | c.1054T>A p.Y352N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV65842572; called by muse, mutect2, varscan2
- RGS12 | c.4273C>T p.P1425S (on ENST00000336727; = p.P777S on NM_198227.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs774798882, COSV58754113; called by muse, mutect2, varscan2
- RNF123 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV59689372; called by muse, mutect2, varscan2
- RNF213 | c.6647G>T p.R2216L | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100300750; called by muse, mutect2, varscan2
- ROCK2 | c.2936C>T p.T979I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs201098449, COSV59960224; called by muse, varscan2
- RP1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109741, COSV99606467; called by muse, mutect2, varscan2
- RPF1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65724513; called by muse, mutect2, varscan2
- RPL10L | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1475518219, COSV100022591; called by muse, mutect2, varscan2
- RPP25L | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 61/137 reads (45%) | catalogued as COSV99426921; called by muse, mutect2, varscan2
- RPRD2 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV64821644; called by muse, mutect2, varscan2
- RPRD2 | c.4372C>T p.P1458S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64821650; called by muse, mutect2, varscan2
- RPS6KB1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56677967; called by muse, mutect2, varscan2
- RYR1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093234, COSV62102317; called by muse, mutect2, varscan2
- SAMD9L | c.4361C>T p.S1454F | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV59082956; called by muse, mutect2, varscan2
- SCN2B | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.094); catalogued as rs1023356508, COSV54050975; called by muse, mutect2, varscan2
- SCN4A | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV71127630; called by muse, mutect2, varscan2
- SCPEP1 | c.952A>T p.R318* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV51854861; called by muse, mutect2, varscan2
- SCRIB | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57589573; called by muse, mutect2, varscan2
- SCYL1 | c.1867G>C p.G623R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.209); catalogued as COSV54213705; called by muse, mutect2
- SEMA4C | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59691435; called by muse, mutect2, varscan2
- SEMA5B | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1282278037, COSV52091166; called by muse, mutect2, varscan2
- SFPQ | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61758913; called by muse, mutect2, varscan2
- SFSWAP | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1441863628, COSV55523363; called by muse, mutect2, varscan2
- SGSM1 | c.2545G>A p.E849K (on ENST00000400359 / NM_001039948.4; = p.E788K on NM_133454.3) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs563457086, COSV63082571; called by muse, mutect2, varscan2
- SIGLEC10 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV59483757; called by muse, mutect2, varscan2
- SIGLEC7 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759671422, COSV58315054; called by muse, mutect2, varscan2
- SIPA1L1 | c.3338G>A p.R1113Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as COSV62171420; called by muse, mutect2, varscan2
- SIRPB1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs766810178, COSV53539427; called by muse, mutect2
- SIRPG | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV53808487; called by muse, mutect2, varscan2
- SLC16A11 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.19); catalogued as COSV57274557; called by muse, mutect2, varscan2
- SLC23A1 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV62297031; called by muse, mutect2, varscan2
- SLC25A27 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV51494341, COSV51497041; called by muse, mutect2
- SLC35C1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV58480363; called by muse, mutect2, varscan2
- SLC35D3 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59377987; called by muse, mutect2, varscan2
- SLC45A1 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 114/159 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.322); catalogued as rs770086226, COSV57097356; called by muse, mutect2, varscan2
- SLC7A2 | c.998G>A p.G333E (on ENST00000494857 / NM_001370338.1; = p.G373E on NM_003046.6) | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1363232782, COSV50258762; called by muse, mutect2, varscan2
- SMARCD3 | c.1096G>A p.E366K (on ENST00000262188 / NM_001003801.2; = p.E353K on NM_003078.4) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99223129; called by muse, mutect2, varscan2
- SMCO1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV58838620; called by muse, mutect2, varscan2
- SNUPN | c.408G>C p.R136S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100419407; called by muse, mutect2
- SNUPN | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs775787446, COSV100419410; called by muse, mutect2
- SNX24 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV54453130; called by muse, mutect2, varscan2
- SOX13 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as COSV99689976; called by muse, mutect2, varscan2
- SOX13 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV65827405; called by muse, mutect2, varscan2
- SPARC | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.908); catalogued as rs371065357, COSV50559135; called by muse, mutect2, varscan2
- SPATA31D1 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 193/298 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV61197912; called by muse, mutect2, varscan2
- SPATA6 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1169356642, COSV64061896; called by muse, mutect2, varscan2
- SPEN | c.4873G>T p.E1625* | Nonsense Mutation (SNP) | VAF 95/144 reads (66%) | catalogued as COSV65364108; called by muse, mutect2, varscan2
- SPHKAP | c.5092G>A p.E1698K (on ENST00000392056 / NM_001142644.2; = p.E1669K on NM_030623.3) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV60884792, COSV60888036; called by muse, mutect2, varscan2
- SPHKAP | c.3545C>G p.S1182C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370348371; called by muse, mutect2, varscan2
- SPI1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV57046558; called by muse, mutect2, varscan2
- SPRY1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100201851; called by muse, mutect2, varscan2
- SPRY1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100201852; called by muse, mutect2, varscan2
- SPRY1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1211718459, COSV59338742; called by muse, mutect2, varscan2
- SSBP2 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100283114, COSV57795621; called by muse, mutect2, varscan2
- STK31 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63457505; called by muse, mutect2, varscan2
- SYNPO2 | c.2938C>T p.Q980* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV61113605; called by muse, mutect2, varscan2
- SYNPR | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55724567; called by muse, mutect2, varscan2
- SYTL4 | c.642-1G>A p.X214_splice | Splice Site (SNP) | VAF 22/31 reads (71%) | catalogued as COSV52169259; called by muse, mutect2, varscan2
- TAF1 | c.1417C>T p.R473W (on ENST00000373790 / NM_138923.4; = p.R494W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs139965533, COSV52117866; called by muse, mutect2, varscan2
- TASOR2 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV60168360; called by muse, mutect2, varscan2
- TAX1BP1 | c.2266G>C p.V756L | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs773672909, COSV99386676; called by muse, mutect2, varscan2
- TBC1D10A | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs145310510, COSV53164678, COSV53164880; called by muse, mutect2, varscan2
- TCTN1 | c.1331G>C p.R444T (on ENST00000551590 / NM_001173975.3; = p.R430T on NM_024549.6) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV66541673; called by muse, mutect2, varscan2
- TEKT3 | c.63C>G p.N21K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58628380; called by muse, mutect2, varscan2
- TGM2 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63931852; called by muse, mutect2, varscan2
- THRB | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 41/75 reads (55%) | catalogued as COSV54981008; called by muse, mutect2, varscan2
- THUMPD3 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.773); catalogued as COSV61506302; called by muse, mutect2, varscan2
- TINAG | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.114); catalogued as rs75755871; called by muse, mutect2, varscan2
- TJAP1 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as COSV52501260, COSV52501893; called by muse, mutect2, varscan2
- TLR4 | c.895G>A p.D299N (on ENST00000355622 / NM_138554.5; = p.D259N on NM_003266.4) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV62923684; called by muse, mutect2, varscan2
- TMC2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461476053, COSV62652818; called by muse, mutect2, varscan2
- TMC5 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 198/280 reads (71%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV66867159; called by muse, mutect2, varscan2
- TMC7 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 62/82 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1479937623, COSV58584981; called by muse, mutect2, varscan2
- TMEM131 | c.4508G>A p.S1503N | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV51779690; called by muse, mutect2, varscan2
- TMEM131L | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1194019035, COSV53646713; called by muse, mutect2, varscan2
- TOGARAM2 | c.2155C>A p.P719T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV65422592, COSV65424021; called by muse, mutect2
- TOR4A | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV62627148; called by muse, mutect2, varscan2
- TP63 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV53211354; called by muse, mutect2, varscan2
- TPTE | c.1340C>T p.S447L (on ENST00000618007 / NM_199261.4; = p.S429L on NM_199259.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs759301774; called by muse, mutect2, varscan2
- TPTE2 | c.964G>A p.G322R (on ENST00000400230 / NM_199254.2; = p.G245R on NM_130785.3) | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55024037; called by muse, mutect2, varscan2
- TPTE2 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.997); catalogued as COSV55024053; called by muse, mutect2
- TRIM39 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.57); catalogued as COSV64955825; called by muse, mutect2, varscan2
- TROAP | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs986187235, COSV99226878; called by muse, varscan2
- TROAP | c.119T>A p.V40E | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99226879; called by muse, mutect2, varscan2
- TRPC7 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs752304356, COSV61460074; called by muse, mutect2, varscan2
- TRPM3 | c.3725G>A p.R1242K (on ENST00000357533 / NM_001366142.2; = p.R1097K on NM_020952.6) | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs1358010007, COSV62589328; called by muse, mutect2, varscan2
- TSPAN12 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs868195538, COSV56080509; called by muse, mutect2, varscan2
- TSR2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100911116; called by muse, mutect2
- TTC21A | c.1900C>G p.R634G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57186623; called by muse, mutect2, varscan2
- TTN | c.91747G>A p.E30583K (on ENST00000591111; = p.E23159K on NM_003319.4) | Missense Mutation (SNP) | VAF 57/152 reads (38%) | PolyPhen possibly damaging (0.751); catalogued as COSV60169010; called by muse, mutect2, varscan2
- TTN | c.91060G>A p.E30354K (on ENST00000591111; = p.E22930K on NM_003319.4) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | PolyPhen benign (0.178); catalogued as rs776682000, COSV60076736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.53378A>C p.H17793P (on ENST00000591111; = p.H10369P on NM_003319.4) | Missense Mutation (SNP) | VAF 35/104 reads (34%) | PolyPhen benign (0.036); catalogued as COSV60169053; called by muse, mutect2, varscan2
- TTN | c.48901G>A p.E16301K (on ENST00000591111; = p.E8877K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | PolyPhen benign (0.033); catalogued as COSV60169071; called by muse, mutect2, varscan2
- TTN | c.33217G>A p.E11073K (on ENST00000591111; = p.E10146K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/199 reads (42%) | PolyPhen benign (0.154); catalogued as COSV60169091; called by muse, mutect2, varscan2
- TTN | c.21526G>A p.A7176T (on ENST00000591111; = p.A6249T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | PolyPhen probably damaging (0.999); catalogued as COSV60169100; called by muse, mutect2, varscan2
- TTN | c.12701C>T p.P4234L (on ENST00000591111; = p.P4188L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV100617053, COSV59947898; called by muse, mutect2, varscan2
- TTN | c.4823G>A p.G1608E (on ENST00000591111; = p.G1562E on NM_003319.4) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV60169108; called by muse, mutect2, varscan2
- TUBGCP3 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 128/226 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs747225423, COSV56184642; called by muse, mutect2, varscan2
- UGT2A3 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 118/211 reads (56%) | catalogued as COSV52360874; called by muse, mutect2, varscan2
- UGT2B7 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs373528265; called by muse, mutect2, varscan2
- UNC13C | c.4572T>A p.F1524L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52893466; called by muse, mutect2, varscan2
- UNC5D | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as rs530508170, COSV54767582; called by muse, mutect2, varscan2
- UPK1B | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs769296250, COSV51766303; called by muse, mutect2, varscan2
- URB2 | c.2492C>T p.S831L | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs753402625, COSV51002166; called by muse, mutect2, varscan2
- USH2A | c.11479C>T p.Q3827* | Nonsense Mutation (SNP) | VAF 68/138 reads (49%) | catalogued as COSV56393704; called by muse, mutect2, varscan2
- USP15 | c.1994C>T p.S665F (on ENST00000280377 / NM_001351159.2; = p.S636F on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV54794827; called by muse, mutect2, varscan2
- USP19 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs770459552, COSV60045887; called by muse, mutect2, varscan2
- USP45 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs772462000, COSV59681433; called by muse, mutect2, varscan2
- VIPAS39 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as rs761604651, COSV53632494; called by muse, mutect2, varscan2
- VPS13B | c.5723C>T p.P1908L | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV62147967; called by muse, mutect2, varscan2
- VPS18 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 84/120 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV55031189; called by muse, mutect2, varscan2
- VWC2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV61487545; called by muse, mutect2, varscan2
- WDR72 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 132/211 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64749588; called by muse, mutect2, varscan2
- WDR72 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV64745624; called by muse, mutect2, varscan2
- WDR88 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs753706528, COSV100866625, COSV63451913; called by muse, mutect2, varscan2
- XIRP2 | c.6240G>A p.M2080I (on ENST00000628543; = p.M2255I on NM_152381.6) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs267598984, COSV54682894; called by muse, mutect2, varscan2
- XKR3 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.031); catalogued as rs1422138117, COSV58886309, COSV58888038; called by muse, mutect2, varscan2
- XPC | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99542365; called by muse, mutect2, varscan2
- YTHDF2 | c.479T>A p.L160* | Nonsense Mutation (SNP) | VAF 54/81 reads (67%) | catalogued as COSV65723708; called by muse, mutect2, varscan2
- ZNF233 | c.513T>G p.N171K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61934026; called by muse, mutect2, varscan2
- ZNF273 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1318475820, COSV60399350; called by muse, mutect2, varscan2
- ZNF28 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV60424045; called by muse, mutect2, varscan2
- ZNF300 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as COSV51038765; called by muse, mutect2, varscan2
- ZNF385B | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV61179125; called by muse, mutect2, varscan2
- ZNF404 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as COSV60987992; called by muse, mutect2
- ZNF454 | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV60769143; called by muse, mutect2, varscan2
- ZNF462 | c.7213G>A p.G2405R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs755322564, COSV52944309; called by muse, mutect2, varscan2
- ZNF521 | c.3124C>T p.H1042Y | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100832547, COSV64128787; called by muse, mutect2, varscan2
- ZNF555 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV62073430; called by muse, mutect2, varscan2
- ZNF557 | c.320C>T p.P107L (on ENST00000414706 / NM_001044388.2; = p.P114L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53274494; called by muse, mutect2, varscan2
- ZNF567 | c.659T>G p.L220R (on ENST00000536254 / NM_001322913.1; = p.L189R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.178); catalogued as COSV62445941; called by muse, mutect2, varscan2
- ZNF592 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV55437962; called by muse, mutect2, varscan2
- ZNF595 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59551421; called by muse, mutect2, varscan2
- ZNF652 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100755611; called by muse, mutect2, varscan2
- ZNF652 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100755612; called by muse, mutect2, varscan2
- ZNF699 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58026162; called by muse, mutect2, varscan2
- ZNF99 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.628); catalogued as COSV68056064; called by muse, mutect2, varscan2
- ZSCAN2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 62/68 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59108497; called by muse, mutect2, varscan2
- ZSCAN25 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV99500592; called by muse, mutect2, varscan2
- ZSCAN25 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 101/268 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.282); catalogued as COSV99500593; called by muse, mutect2, varscan2
- ADCK1 | c.1501_1517del p.R501Afs*3 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- GPR179 | c.2851G>A p.E951K (on ENST00000621958; = p.E950K on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHA1 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- IGHV3-21 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); called by muse, varscan2
- MLLT6 | c.1781C>G p.S594C | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRROS | c.1913_1915delinsTT p.P638Lfs*120 | Frame Shift Del (DEL) | VAF 61/172 reads (35%) | called by pindel, varscan2*
- SPTAN1 | c.4568C>T p.S1523F | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPTE | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TPTE | c.1504T>C p.F502L (on ENST00000618007 / NM_199261.4; = p.F484L on NM_199259.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- TRBV3-1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF181 | c.1210del p.Q404Nfs*8 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1077G>A p.G359= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55293625; called by muse, mutect2, varscan2
- ABCC8 | c.765C>T p.I255= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs753335564, COSV56849772; called by muse, mutect2, varscan2
- ACAD9 | c.60G>A p.L20= | Silent (SNP) | VAF 77/153 reads (50%) | catalogued as COSV58308554; called by muse, mutect2, varscan2
- ACP7 | c.312G>A p.G104= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1352053517, COSV58699979; called by muse, mutect2, varscan2
- ACSL6 | c.1221G>A p.R407= (on ENST00000379240; = p.R432= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV57300873; called by muse, mutect2, varscan2
- ADA2 | c.1062C>T p.F354= (on ENST00000262607; = p.F113= on NM_177405.3) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV52832170; called by muse, mutect2, varscan2
- ADAM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs267601919, COSV55858842; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1893C>T p.S631= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV54455891; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.600G>A p.A200= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs759827399, COSV58444848; called by muse, mutect2, varscan2
- AHNAK | c.11430C>T p.P3810= | Silent (SNP) | VAF 201/548 reads (37%) | catalogued as rs1308725204, COSV57219403; called by muse, mutect2, varscan2
- AHSG | c.9C>T p.S3= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs934229190, COSV99890094, COSV99890482; called by muse, mutect2
- AMDHD2 | c.480C>T p.L160= | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as COSV53551380; called by muse, mutect2, varscan2
- ANK1 | c.963C>T p.V321= | Silent (SNP) | VAF 77/164 reads (47%) | catalogued as COSV55886225; called by muse, mutect2, varscan2
- ANKS4B | c.40C>T p.L14= | Silent (SNP) | VAF 79/128 reads (62%) | catalogued as COSV61139555; called by muse, mutect2, varscan2
- ANXA10 | c.120G>A p.L40= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV63739458; called by muse, mutect2, varscan2
- ANXA3 | c.657C>T p.I219= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV53715541; called by muse, mutect2, varscan2
- ANXA7 | c.1392G>A p.K464= (on ENST00000372919 / NM_001320880.2; = p.K442= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV65823760; called by muse, mutect2, varscan2
- ANXA9 | c.339C>T p.P113= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as COSV64485154; called by muse, mutect2, varscan2
- AOAH | c.93C>T p.S31= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99332997; called by muse, mutect2, varscan2
- APBA1 | c.1149G>A p.Q383= | Silent (SNP) | VAF 83/112 reads (74%) | catalogued as COSV55231252; called by muse, mutect2, varscan2
- ARID5A | c.684C>T p.S228= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV100673602; called by muse, mutect2, varscan2
- ASB5 | c.615C>T p.L205= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV56672190; called by muse, mutect2, varscan2
- ATP10A | c.2235C>T p.V745= | Silent (SNP) | VAF 47/67 reads (70%) | catalogued as COSV63519813; called by muse, mutect2, varscan2
- ATP12A | c.867C>T p.A289= | Silent (SNP) | VAF 128/204 reads (63%) | catalogued as COSV99517784; called by muse, mutect2, varscan2
- ATP12A | c.2811C>T p.F937= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as COSV54518880; called by muse, mutect2, varscan2
- ATP1A3 | c.1482C>T p.S494= (on ENST00000545399 / NM_001256214.2; = p.S481= on NM_152296.5) | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV57489034; called by muse, mutect2, varscan2
- ATP2B3 | c.1881G>A p.R627= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV54852865; called by muse, mutect2, varscan2
- ATP6V1B1 | c.111C>T p.P37= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV52266426; called by muse, mutect2, varscan2
- BAIAP2 | c.1257G>A p.E419= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV58337275; called by muse, mutect2, varscan2
- BRINP1 | c.1770C>T p.I590= | Silent (SNP) | VAF 62/176 reads (35%) | catalogued as COSV56305012; called by muse, mutect2, varscan2
- BRINP2 | c.2094G>A p.R698= | Silent (SNP) | VAF 77/197 reads (39%) | catalogued as COSV64178526; called by muse, mutect2, varscan2
- BRINP3 | c.288C>T p.F96= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs867310371, COSV66511698, COSV66528585; called by muse, mutect2, varscan2
- CACNA1A | c.3447C>T p.I1149= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs781300443, COSV100802539, COSV64202829; called by muse, mutect2, varscan2
- CACNA1E | c.2571G>A p.K857= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV62383267; called by muse, mutect2
- CACNA2D3 | c.3087C>T p.P1029= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs1374760990, COSV55534264; called by muse, mutect2
- CADPS2 | c.2253C>T p.L751= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1210042946, COSV57371788; called by muse, mutect2, varscan2
- CAMK1G | c.726C>T p.F242= | Silent (SNP) | VAF 69/199 reads (35%) | catalogued as COSV50523432; called by muse, mutect2, varscan2
- CC2D1A | c.684G>A p.L228= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs764693828, COSV100528528; called by muse, mutect2, varscan2
- CCDC60 | c.1161G>A p.R387= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV100554684, COSV59543517; called by muse, mutect2, varscan2
- CCDC68 | c.306C>T p.L102= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV61603731; called by muse, mutect2, varscan2
- CCN4 | c.933C>T p.I311= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as COSV51529777; called by muse, mutect2, varscan2
- CD8A | c.540C>T p.A180= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV52158225; called by muse, mutect2
- CDC42BPB | c.3990C>T p.L1330= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100775299, COSV63475788; called by muse, mutect2, varscan2
- CDH8 | c.237G>A p.P79= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV54845740; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5268A>G p.Q1756= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV62575717; called by muse, mutect2, varscan2
- CEACAM16 | c.321C>T p.I107= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV69187389; called by muse, mutect2, varscan2
- CEACAM5 | c.1815C>T p.Y605= | Silent (SNP) | VAF 115/261 reads (44%) | catalogued as rs782764034, COSV55753176; called by muse, mutect2, varscan2
- CHRM2 | c.1353T>C p.F451= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as COSV57776769, COSV57777825; called by muse, mutect2, varscan2
- CHRNB2 | c.672C>T p.I224= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs1471557903, COSV63808781; called by muse, mutect2, varscan2
- CIB2 | c.123C>T p.L41= | Silent (SNP) | VAF 84/101 reads (83%) | catalogued as rs780117405, COSV51947814; called by muse, mutect2, varscan2
- CLEC4E | c.492C>T p.F164= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV55225953; called by muse, mutect2, varscan2
- CLVS1 | c.369C>T p.I123= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs200541190, COSV57971814, COSV57984735; called by muse, mutect2, varscan2
- CNTNAP2 | c.2664G>A p.E888= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV62211022; called by muse, mutect2, varscan2
- COL14A1 | c.4644C>T p.G1548= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV52859673; called by muse, mutect2, varscan2
- CRYBA4 | c.294C>T p.A98= | Silent (SNP) | VAF 94/247 reads (38%) | catalogued as COSV61322346; called by muse, mutect2, varscan2
- CSF2RB | c.2295C>T p.G765= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV53258876; called by muse, mutect2, varscan2
- CSMD1 | c.8058G>A p.P2686= (on ENST00000520002; = p.P2685= on NM_033225.6) | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs376009667; called by muse, mutect2, varscan2
- CYP4F12 | c.1366C>T p.L456= | Silent (SNP) | VAF 113/269 reads (42%) | catalogued as COSV61172776, COSV61174877; called by muse, mutect2, varscan2
- DAOA | c.171G>A p.R57= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV61602861; called by muse, mutect2, varscan2
- DCLK3 | c.504G>A p.K168= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs1167092817, COSV69363832; called by muse, mutect2, varscan2
- DDI1 | c.483G>A p.K161= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV56369289; called by muse, mutect2, varscan2
- DDX60L | c.1644G>A p.E548= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52716586; called by muse, mutect2, varscan2
- DEGS2 | c.834G>A p.K278= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV59784741; called by muse, mutect2, varscan2
- DISP3 | c.3792G>A p.E1264= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV53821213; called by muse, mutect2, varscan2
- DNAH17 | c.6369C>T p.S2123= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs761397602, COSV67757637; called by muse, mutect2, varscan2
- DOCK6 | c.5001C>T p.P1667= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs201362444, COSV53910755; called by muse, mutect2
- DSCAML1 | c.2220G>A p.R740= (on ENST00000321322; = p.R680= on NM_020693.4) | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV58395767; called by muse, mutect2, varscan2
- ECPAS | c.4602C>T p.S1534= | Silent (SNP) | VAF 64/92 reads (70%) | catalogued as COSV99398480; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.528C>T p.I176= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1182628502, COSV55744680; called by muse, mutect2, varscan2
- EFNB1 | c.990C>T p.I330= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as rs1296902174, COSV52662149, COSV99214879; called by muse, mutect2, varscan2
- EHBP1L1 | c.54C>T p.F18= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1475588944, COSV57079757; called by muse, mutect2
- ELF3 | c.501G>A p.Q167= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV100668759, COSV62839100; called by muse, mutect2, varscan2
- ELOA2 | c.1026C>T p.N342= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as COSV55302311; called by muse, mutect2, varscan2
- ENTPD3 | c.876G>A p.R292= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV57195173; called by muse, mutect2, varscan2
- EPHA4 | c.2436C>T p.I812= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs749559340, COSV56037137; called by muse, mutect2, varscan2
- EPHB2 | c.2259C>T p.L753= (on ENST00000400191 / NM_001309193.2; = p.L754= on NM_004442.7) | Silent (SNP) | VAF 75/109 reads (69%) | catalogued as rs368213597, COSV65863757; called by muse, mutect2, varscan2
- ESRRB | c.849C>T p.I283= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV55063539; called by muse, mutect2, varscan2
- ETV3 | c.159C>T p.V53= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs1189040239, COSV58748220; called by muse, mutect2, varscan2
- EXPH5 | c.627C>T p.F209= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV56204551; called by muse, mutect2, varscan2
- EYA2 | c.126C>T p.A42= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs1304461721, COSV57946416; called by muse, mutect2, varscan2
- EYS | c.534G>A p.L178= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV60991463; called by muse, mutect2, varscan2
- FAM111B | c.1209G>A p.P403= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as COSV59111562; called by muse, mutect2, varscan2
- FAM193A | c.2464C>T p.L822= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV61196117; called by muse, mutect2, varscan2
- FAM47C | c.6G>A p.G2= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV63728078; called by muse, mutect2
- FBXL14 | c.840C>T p.R280= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV59336956; called by muse, mutect2, varscan2
- FBXO3 | c.54C>T p.T18= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1175880854, COSV99682212; called by muse, mutect2
- FOXP1 | c.45C>A p.A15= | Silent (SNP) | VAF 96/219 reads (44%) | catalogued as COSV59523599; called by muse, mutect2, varscan2
- FSIP2 | c.18336C>T p.I6112= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as COSV58091170; called by muse, mutect2, varscan2
- FYB2 | c.861C>T p.I287= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as rs748913005, COSV58583402; called by muse, mutect2, varscan2
- GAL3ST2 | c.210C>T p.I70= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV51950467; called by muse, mutect2, varscan2
- GALNT5 | c.1692G>A p.E564= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52038988, COSV52039736; called by muse, mutect2, varscan2
- GCC1 | c.2034G>A p.E678= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs746269017, COSV100365551, COSV58462886; called by muse, mutect2, varscan2
- GFM1 | c.108T>C p.S36= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV51833791; called by muse, mutect2, varscan2
- GLI2 | c.4617C>T p.I1539= (on ENST00000361492 / NM_001374353.1; = p.I1556= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/242 reads (43%) | catalogued as rs144803259; called by muse, mutect2, varscan2
- GNAI2 | c.534C>T p.T178= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV99807067; called by muse, mutect2, varscan2
- GPRASP2 | c.1317C>T p.A439= | Silent (SNP) | VAF 75/123 reads (61%) | catalogued as COSV59991889; called by muse, mutect2, varscan2
- GRIN2A | c.3765G>A p.Q1255= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as COSV58042315; called by muse, mutect2, varscan2
- HGFAC | c.936C>T p.S312= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs771972328, COSV66977072; called by muse, mutect2, varscan2
- HGS | c.1788C>T p.A596= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as rs200749825, COSV100230549; called by muse, mutect2, varscan2
- HMGCS2 | c.219G>A p.L73= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV65568429; called by muse, mutect2, varscan2
- HTR5A | c.243C>T p.S81= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV55284748; called by muse, mutect2, varscan2
- IGHV4-34 | c.366G>C p.A122= | Silent (SNP) | VAF 108/313 reads (35%) | catalogued as rs772715869; called by muse, mutect2, varscan2
- IGKV1D-13 | c.51C>T p.L17= | Silent (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- ILDR1 | c.1449G>A p.E483= (on ENST00000344209 / NM_001199799.2; = p.E439= on NM_175924.4) | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs544136698, COSV56551315; called by muse, mutect2, varscan2
- INO80C | c.42C>T p.P14= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV52034465; called by muse, mutect2, varscan2
- INSR | c.1191C>A p.I397= | Silent (SNP) | VAF 64/151 reads (42%) | catalogued as COSV57166069; called by muse, mutect2, varscan2
- INTS12 | c.1116C>T p.G372= | Silent (SNP) | VAF 109/209 reads (52%) | catalogued as rs765984885, COSV60862796; called by muse, mutect2, varscan2
- ITIH4 | c.1152C>T p.T384= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as rs753455021, COSV56574274; called by muse, mutect2, varscan2
- JDP2 | c.192G>T p.V64= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV50868127; called by muse, mutect2, varscan2
- KANK4 | c.1011G>A p.V337= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as COSV62987652; called by muse, mutect2, varscan2
- KCNA5 | c.576C>T p.S192= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV99363938; called by muse, mutect2, varscan2
- KCNK1 | c.309C>T p.D103= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV64038829; called by muse, mutect2, varscan2
- KCNQ1 | c.1092C>T p.F364= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV50116552; called by muse, mutect2, varscan2
- KCNT2 | c.1518G>A p.K506= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs947886420, COSV54090013; called by muse, mutect2, varscan2
- KDM6B | c.303C>T p.L101= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99641665; called by muse, mutect2, varscan2
- KIR3DL1 | c.645C>T p.I215= | Silent (SNP) | VAF 192/460 reads (42%) | catalogued as rs375412872; called by muse, mutect2, varscan2
- KLHL18 | c.507G>A p.E169= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV51743964, COSV51746910; called by muse, mutect2, varscan2
- KRT33B | c.450C>T p.S150= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as rs762589441, COSV52441451; called by muse, mutect2, varscan2
- KRT4 | c.1308C>T p.I436= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as rs745647700, COSV53408372; called by muse, mutect2, varscan2
- L1TD1 | c.1269G>A p.G423= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs1348162684, COSV63133669; called by muse, mutect2
- LARP1B | c.432C>T p.I144= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as COSV52799463; called by muse, mutect2, varscan2
- LGALS13 | c.9T>A p.S3= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV55680315; called by muse, mutect2, varscan2
- LINGO4 | c.45C>T p.P15= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100561963; called by muse, mutect2, varscan2
- LMCD1 | c.462C>T p.R154= | Silent (SNP) | VAF 53/189 reads (28%) | catalogued as COSV99337616; called by muse, mutect2, varscan2
- LPAR4 | c.885C>T p.I295= | Silent (SNP) | VAF 62/78 reads (79%) | catalogued as COSV70912423, COSV70912961; called by muse, mutect2, varscan2
- LRRC20 | c.228C>T p.L76= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1161217148, COSV62938670; called by muse, mutect2, varscan2
- LY9 | c.879G>A p.R293= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs754708171, COSV54435424; called by muse, mutect2, varscan2
- LYSMD1 | c.606C>T p.V202= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV64423192; called by muse, mutect2, varscan2
- MAGEB6 | c.699C>T p.F233= | Silent (SNP) | VAF 58/81 reads (72%) | catalogued as rs867212343, COSV66871960; called by muse, mutect2, varscan2
- MAGEC1 | c.1854G>A p.G618= | Silent (SNP) | VAF 215/311 reads (69%) | catalogued as COSV53574327; called by muse, mutect2, varscan2
- MAMLD1 | c.1887C>T p.A629= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as COSV99476110; called by muse, mutect2, varscan2
- MAN2A2 | c.312C>T p.P104= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as rs779079949, COSV100847891; called by muse, mutect2, varscan2
- MAP1B | c.5889C>T p.T1963= | Silent (SNP) | VAF 83/166 reads (50%) | catalogued as rs769967633, COSV99702499; called by muse, mutect2, varscan2
- MAP3K13 | c.2580G>A p.E860= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV53991654; called by muse, mutect2, varscan2
- MAPK8IP1 | c.933C>T p.S311= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs760397061, COSV99571524; called by muse, mutect2, varscan2
- MARVELD2 | c.171C>T p.F57= | Silent (SNP) | VAF 72/122 reads (59%) | catalogued as rs142002229; called by muse, mutect2, varscan2
- MATN3 | c.435C>T p.S145= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV68100146; called by muse, mutect2
- MATR3 | c.1668C>T p.A556= | Silent (SNP) | VAF 69/138 reads (50%) | catalogued as rs1299483173, COSV63078176; called by muse, mutect2, varscan2
- METRNL | c.342C>T p.S114= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV60761127; called by muse, mutect2, varscan2
- MGAM | c.1941C>T p.N647= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV72075016; called by muse, mutect2, varscan2
- MICAL3 | c.2533C>T p.L845= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs748449708, COSV52899954; called by muse, mutect2, varscan2
- MON1A | c.1359G>A p.S453= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs374746320, COSV56561500; called by muse, mutect2, varscan2
- MOV10L1 | c.213G>A p.L71= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as rs767902709, COSV53174520; called by muse, mutect2, varscan2
193 further variants in this file (0 protein-altering or splice-affecting, 165 silent, 28 other) are not listed here.
